HCMI case HCM-EXPT-1039-C34 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/5314a3fc-6129-4d68-89f5-1084bfd0442d

Demographics
Sex at birth: male; Year of birth: 1941.

Diagnoses (1)
1. Minimally invasive adenocarcinoma, mucinous: ICD-O-3 morphology code: 8257/3; ICD-10 code: C34.9; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Middle lobe, lung; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 76.0 years (27,765 days); Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-1039-C34-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-1039-C34-01A-01-S1-HE: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-1039-C34-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 15; Percent tumor nuclei: 26; Percent normal cells: 25; Percent necrosis: 30; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
